Surgical pathology report (de-identified scan), TCGA case TCGA-DW-7837, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DW-7837-01A (Primary Tumor).

[page 1 of 3]
DIAGNOSIS:

1. Mass, right kidney (partial nephrectomy): Renal cell carcinoma, papillary type I; incipient lesion is seen in adjacent kidney parenchyma, see note.
2. Fat, overlying tumor (excision): Fibroadipose tissue, no tumor seen.

NOTE:

Kidney Partial Nephrectomy Summary Table

Macroscopic

Specimen Type: Partial nephrectomy

Laterality: Right

Tumor Size: 5.5 x 4.2 x 2.3 cm

Focality: Unifocal with adjacent incipient lesion

Macro Extent of Tumor: Limited to the kidney

Microscopic

Histologic Type: Renal cell carcinoma, papillary type I

Extent of Invasion

Primary Tumor(pT): pT1b

Regional Lymph Nodes(pN): pNX

Distant Metastasis(pM): pMX

Margins: Can not be assessed.

CLINICAL INFORMATION: Brief Clinical History: [REDACTED] with bilat multifocal tumors

Patient Identification

[page 2 of 3]
[REDACTED]

Specimen Taken For Protocol: [REDACTED]

PROCEDURE: Pre-Operative Diagnosis: Bilateral renal masses Post-Operative
Diagnosis: Bilateral renal masses Operative Findings: 3 cm R upper
pole tumor with satellite lesion

SPECIMENS SUBMITTED: 1. KIDNEY, RIGHT, Mass
2. FAT, Overlying tumor

GROSS DESCRIPTION: Received are 2 formalin-filled containers labeled with the patient's name, medical record number, and further described as follows:

1. "Right kidney mass". Received fresh from OR labeled with the patient's name, medical record number and "right kidney mass" is a 5.5 x 4.2 x 2.3 cm, tan, friable tumor, with a small rim of normal parenchyma, a second nodule measuring 0.5 x 0.4 cm is present. Approximately 50% of both tumors and 5 mL of normal kidney parenchyma procured for Research. Macroscopic images were taken. The procurement was performed by [REDACTED]
[REDACTED] Received in Surgical Pathology, the specimen is serially sectioned and representative sections are submitted in white cassettes labeled [REDACTED] through 1D for serial sectioning.

2. "Fat overlying tumor". The specimen consists of 2 pieces of yellow adipose tissue measuring 3.5 x 3 x 0.5 cm in aggregate. The specimen is serially sectioned and no gross tumor identified. The specimen is entirely submitted in white cassettes labeled [REDACTED] through 2E for serial sectioning.

[REDACTED]

Source: NCI Genomic Data Commons file dee3ff48-8e01-4068-a245-4e442258650e (TCGA-DW-7837.D915D81F-5789-41C3-92E1-8ADB1012FAE4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).